Somatic mutation profile of tumor specimen C3N-01525-03 (aliquot CPT0095890074) from CPTAC case C3N-01525, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 77.3 years (28,217 days).
Specimen C3N-01525-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e995c39b-26e4-4bbb-9fc7-faf4a28c05b8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01525-31 (Blood Derived Normal), aliquot CPT0095910002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/60110e7d-ca1f-4b85-b58f-2e31cb306bd5

The open-access MAF lists 106 somatic variants for this specimen: 80 protein-altering or splice-affecting, 17 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, Silent 17, Frame Shift Del 5, Intron 5, Nonsense Mutation 4, Frame Shift Ins 2, In Frame Del 1, Splice Region 1, 3'UTR 1, 5'Flank 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHD4 | c.3341G>A p.R1114Q (on ENST00000357008 / NM_001363606.2; = p.R1127Q on NM_001273.5) | Missense Mutation (SNP) | VAF 45/146 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs886039917, COSV58895679; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.110C>G p.S37C | Missense Mutation (SNP) | VAF 69/312 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.331A>G p.K111E | Missense Mutation (SNP) | VAF 8/26 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs1057519933, COSV55878486, COSV56029794; ClinVar: likely pathogenic; called by muse, mutect2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 180/378 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA6 | c.4180G>A p.A1394T | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as rs1173154389; called by muse, mutect2, varscan2
- ARHGEF10L | c.2032G>A p.G678S | Missense Mutation (SNP) | VAF 70/165 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1355345589; called by muse, mutect2, varscan2
- ARID3B | c.1384C>T p.R462W | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs753085247; called by muse, mutect2, varscan2
- ATP2A1 | c.667G>A p.V223M | Missense Mutation (SNP) | VAF 90/242 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs767886671; called by muse, mutect2
- CACNA1E | c.4102G>A p.V1368I | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.693); catalogued as rs574530214, COSV62402477; called by muse, mutect2, varscan2
- CAMTA1 | c.3553A>G p.S1185G | Missense Mutation (SNP) | VAF 55/223 reads (25%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as rs954409338; called by muse, mutect2, varscan2
- DLG5 | c.2119C>T p.R707W | Missense Mutation (SNP) | VAF 144/268 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1488016884, COSV64948531; called by muse, mutect2, varscan2
- EPHB6 | c.2201G>A p.R734Q | Missense Mutation (SNP) | VAF 233/836 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as rs201556658, COSV63892635; called by muse, mutect2, varscan2
- GRIA4 | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs151104343; called by muse, mutect2, varscan2
- GRIK5 | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); catalogued as rs201959426; called by muse, mutect2, varscan2
- HEPACAM | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 163/477 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs751732183, COSV53430381; called by muse, mutect2, varscan2
- HRNR | c.8408G>A p.S2803N | Missense Mutation (SNP) | VAF 151/406 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.076); catalogued as rs552697734; called by muse, mutect2, varscan2
- HSF4 | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 190/523 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV50456664; called by muse, mutect2, varscan2
- JAG1 | c.1444G>A p.D482N | Missense Mutation (SNP) | VAF 115/350 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.22); catalogued as rs766370717; called by muse, mutect2, varscan2
- KANSL1 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 69/260 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.048); catalogued as rs376632173; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- KIAA1109 | c.9572T>G p.L3191R | Missense Mutation (SNP) | VAF 44/167 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV52661427; called by muse, mutect2, varscan2
- KIAA2026 | c.700C>T p.R234* | Nonsense Mutation (SNP) | VAF 139/382 reads (36%) | catalogued as rs1228518521; called by muse, mutect2, varscan2
- LGI2 | c.236G>A p.R79Q | Missense Mutation (SNP) | VAF 65/215 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.138); catalogued as rs139692298, COSV66123183; called by muse, mutect2, varscan2
- MAMLD1 | c.1039C>T p.H347Y | Missense Mutation (SNP) | VAF 85/227 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.636); catalogued as rs1005490291; called by muse, mutect2, varscan2
- MAP1S | c.2587C>T p.R863W | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs749473307; called by muse, mutect2, varscan2
- MED12 | c.67G>T p.D23Y | Missense Mutation (SNP) | VAF 105/216 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61334558; called by muse, mutect2, varscan2
- NICN1 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 72/203 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs748614806, COSV56469044, COSV56471088; called by muse, mutect2, varscan2
- NKTR | c.880C>T p.R294* | Nonsense Mutation (SNP) | VAF 51/151 reads (34%) | catalogued as rs1479671676; called by muse, mutect2, varscan2
- NLRP4 | c.1496T>G p.L499W | Missense Mutation (SNP) | VAF 53/175 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.096); catalogued as rs907483906, COSV56708637, COSV56710687; called by muse, mutect2, varscan2
- NOS3 | c.1163G>A p.R388Q | Missense Mutation (SNP) | VAF 68/289 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.713); catalogued as rs767108240; called by muse, mutect2, varscan2
- NR5A1 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 79/183 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs752292248, COSV65295683; called by muse, mutect2, varscan2
- OR10A7 | c.260C>A p.S87Y | Missense Mutation (SNP) | VAF 97/278 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV58278864; called by muse, mutect2, varscan2
- OR8D1 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs562758196, COSV63441771; called by muse, mutect2, varscan2
- PARP4 | c.2860T>C p.W954R | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1420177812; called by muse, mutect2, varscan2
- PAX1 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 55/156 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68271303; called by muse, mutect2, varscan2
- PIK3R1 | c.1685G>C p.R562P (on ENST00000521381 / NM_181523.3; = p.R292P on NM_181504.4) | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV57124822; called by muse, mutect2, varscan2
- POMT2 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 25/305 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.351); catalogued as rs772255938; ClinVar: uncertain significance; called by muse, mutect2
- PRMT8 | c.779T>C p.V260A | Missense Mutation (SNP) | VAF 42/153 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as rs747021868; called by muse, mutect2, varscan2
- RAD54B | c.651C>G p.I217M | Missense Mutation (SNP) | VAF 59/303 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.076); catalogued as COSV60250652; called by muse, mutect2, varscan2
- ROPN1L | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 60/185 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1190893461; called by muse, mutect2, varscan2
- RYR1 | c.9560G>A p.R3187Q | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs1171145743; called by muse, mutect2, varscan2
- SRC | c.1438C>T p.R480W | Missense Mutation (SNP) | VAF 51/122 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs1479989919; called by muse, mutect2, varscan2
- STARD6 | c.337G>A p.D113N | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as rs145044397, COSV104410849; called by muse, mutect2, varscan2
- TGFBRAP1 | c.2228G>A p.R743H | Missense Mutation (SNP) | VAF 118/353 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as rs755371712, COSV51513640; called by muse, mutect2, varscan2
- ADNP | c.1345T>C p.C449R | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARID1A | c.5465del p.P1822Hfs*61 | Frame Shift Del (DEL) | VAF 52/163 reads (32%) | called by mutect2, pindel, varscan2
- ARID5B | c.1431_1434del p.L478* | Frame Shift Del (DEL) | VAF 29/61 reads (48%) | called by mutect2, pindel, varscan2
- ASH1L | c.3679T>A p.F1227I | Missense Mutation (SNP) | VAF 89/229 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- B4GALT1 | c.1003G>T p.V335F | Missense Mutation (SNP) | VAF 120/330 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- C2orf68 | c.296_307del p.E99_S103delinsA | In Frame Del (DEL) | VAF 18/104 reads (17%) | called by mutect2, pindel, varscan2
- CHPF | c.2263G>A p.G755S | Missense Mutation (SNP) | VAF 87/240 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- ERO1B | c.818A>G p.K273R | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FAM221A | c.793G>C p.D265H | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- FOXA3 | c.781G>C p.E261Q | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- FSIP2 | c.9247G>T p.V3083F | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GLCE | c.640A>G p.I214V | Missense Mutation (SNP) | VAF 48/135 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- GUCY1B1 | c.1814C>T p.S605F | Missense Mutation (SNP) | VAF 51/159 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- HNRNPH3 | c.58_61dup p.R21Pfs*68 | Frame Shift Ins (INS) | VAF 42/181 reads (23%) | called by mutect2, pindel, varscan2
- KCNA7 | c.307C>G p.L103V | Missense Mutation (SNP) | VAF 177/519 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- KCNH3 | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 134/375 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- KIAA2013 | c.1585G>A p.D529N | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KMT2E | c.4373C>T p.T1458I | Missense Mutation (SNP) | VAF 82/367 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- MX1 | c.1951_1952del p.T651Afs*20 | Frame Shift Del (DEL) | VAF 54/199 reads (27%) | called by mutect2, pindel, varscan2
- MYO10 | c.2464A>T p.K822* | Nonsense Mutation (SNP) | VAF 82/202 reads (41%) | called by muse, mutect2, varscan2
- NIPSNAP3A | c.239G>T p.R80I | Missense Mutation (SNP) | VAF 82/225 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- OTP | c.964A>G p.M322V | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- PLSCR5 | c.315C>A p.S105R | Missense Mutation (SNP) | VAF 58/180 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- RYR2 | c.4634C>A p.A1545E | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- SBF2 | c.1860+7del | Splice Region (DEL) | VAF 14/46 reads (30%) | called by mutect2, pindel, varscan2
- SLC25A51 | c.163del p.L55Sfs*18 | Frame Shift Del (DEL) | VAF 58/195 reads (30%) | called by mutect2, pindel, varscan2
- SLC6A19 | c.1277G>A p.C426Y | Missense Mutation (SNP) | VAF 158/461 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- STAT5A | c.298C>G p.R100G | Missense Mutation (SNP) | VAF 69/180 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRABD2B | c.886C>A p.R296S | Missense Mutation (SNP) | VAF 38/180 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TRAPPC13 | c.265G>C p.D89H | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- VIM | c.817C>A p.R273S | Missense Mutation (SNP) | VAF 77/334 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZFC3H1 | c.4273G>A p.E1425K | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ZFP36L2 | c.548dup p.R184Afs*290 | Frame Shift Ins (INS) | VAF 227/765 reads (30%) | called by mutect2, pindel, varscan2
- ZIC3 | c.764G>A p.W255* | Nonsense Mutation (SNP) | VAF 105/308 reads (34%) | called by muse, mutect2, varscan2
- ZNF331 | c.1172_1178del p.A391Vfs*7 | Frame Shift Del (DEL) | VAF 69/186 reads (37%) | called by mutect2, pindel, varscan2
- ZNF624 | c.1250A>G p.K417R | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- ZNF865 | c.2276C>T p.A759V | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT tolerated (0.12); called by muse, mutect2, varscan2
- BMP2 | c.264T>G p.G88= | Silent (SNP) | VAF 64/152 reads (42%) | called by muse, mutect2
- EPHA2 | c.1191G>T p.V397= | Silent (SNP) | VAF 116/380 reads (31%) | called by muse, mutect2, varscan2
- FRMPD3 | c.2607G>A p.P869= | Silent (SNP) | VAF 115/305 reads (38%) | catalogued as rs1451679884; called by muse, mutect2, varscan2
- GALNT3 | c.588A>G p.E196= | Silent (SNP) | VAF 58/188 reads (31%) | called by muse, mutect2, varscan2
- HDAC4 | c.882C>T p.S294= | Silent (SNP) | VAF 70/219 reads (32%) | catalogued as rs911608166, COSV100612898; called by muse, mutect2, varscan2
- ITPRID1 | c.1299G>A p.P433= | Silent (SNP) | VAF 28/109 reads (26%) | catalogued as rs1277567601; called by muse, mutect2, varscan2
- KLHL33 | c.255T>C p.P85= | Silent (SNP) | VAF 98/290 reads (34%) | called by muse, mutect2, varscan2
- MAP1A | c.3774C>T p.P1258= | Silent (SNP) | VAF 95/231 reads (41%) | called by muse, mutect2, varscan2
- MICAL1 | c.2658C>T p.D886= | Silent (SNP) | VAF 56/168 reads (33%) | called by muse, mutect2, varscan2
- MTUS2 | c.2013G>A p.P671= | Silent (SNP) | VAF 61/147 reads (41%) | catalogued as rs1424838911, COSV70916627; called by muse, mutect2, varscan2
- NUBP2 | c.405G>A p.P135= | Silent (SNP) | VAF 88/254 reads (35%) | catalogued as rs144072283; called by muse, mutect2, varscan2
- PCDHA6 | c.1824G>A p.S608= | Silent (SNP) | VAF 165/472 reads (35%) | catalogued as rs782789312, COSV100971175, COSV65343226, COSV65345214; called by muse, mutect2, varscan2
- PCNX3 | c.1473G>A p.T491= | Silent (SNP) | VAF 144/395 reads (36%) | catalogued as rs887263138; called by muse, mutect2, varscan2
- QPCTL | c.1011C>T p.P337= | Silent (SNP) | VAF 47/123 reads (38%) | catalogued as rs777466140; called by muse, mutect2, varscan2
- SYCP2L | c.111T>C p.D37= | Silent (SNP) | VAF 51/128 reads (40%) | called by muse, mutect2, varscan2
- TDRD6 | c.684G>A p.S228= | Silent (SNP) | VAF 33/153 reads (22%) | catalogued as COSV60175890; called by muse, mutect2, varscan2
- ZDHHC23 | c.786C>T p.A262= | Silent (SNP) | VAF 68/210 reads (32%) | called by muse, mutect2, varscan2
- ELK1 | c.-84G>A | 5'UTR (SNP) | VAF 23/73 reads (32%) | called by muse, mutect2, varscan2
- FAM27E5 | n.177C>T | RNA (SNP) | VAF 72/247 reads (29%) | catalogued as rs771362103; called by muse, mutect2, varscan2
- KCTD1 | c.-15-46044G>A | Intron (SNP) | VAF 46/159 reads (29%) | called by muse, mutect2, varscan2
- MMAB | c.*790G>T | 3'UTR (SNP) | VAF 27/81 reads (33%) | called by muse, mutect2, varscan2
- NPIPA8 | chr16:18340525 A>G | 5'Flank (SNP) | VAF 40/384 reads (10%) | called by muse, mutect2, varscan2
- RBMX2 | c.173+10C>A | Intron (SNP) | VAF 20/62 reads (32%) | called by muse, mutect2, varscan2
- STRA6 | c.597+20G>A | Intron (SNP) | VAF 137/371 reads (37%) | catalogued as rs1246268008; called by muse, mutect2, varscan2
- TMX2 | c.250+19T>G | Intron (SNP) | VAF 75/186 reads (40%) | called by muse, mutect2, varscan2
- YARS1 | c.58-35C>G | Intron (SNP) | VAF 110/276 reads (40%) | called by muse, mutect2, varscan2
